Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0EN, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0EN-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient:
FMP/SSN:
DOB/Age/Sex:
Location:
Physician(s):

Sex: 1 F Race: WHITE

Specimen #:

Taken:
Received:
Reported:

****AMENDED****

1CB-0-3
Carcinoma, infiltrating lobular, Nos 8520/
Site: Breast, Nos C50.9 1/26/11 lu

SPECIMEN: RIGHT BREAST NEEDLE LOC

FINAL DIAGNOSIS:

- BREAST, RIGHT, NEEDLE LOCALIZATION BIOPSY:
- MULTIFOCAL INFILTRATING LOBULAR CARCINOMA, WELL-TO-MODERATELY DIFFERENTIATED.
- THE MAXIMAL TUMOR SIZE IS ESTIMATED TO BE 2.8 CM (SEE COMMENT).
- THE SURGICAL MARGIN IS POSITIVE FOR TUMOR (SLIDE A5).
- MULTIFOCAL LOBULAR CARCINOMA IN SITU.

COMMENT: The tumor is multifocal and present on seven consecutive sections. Based on this finding, the tumor size is estimated to be 2.8 cm in the largest dimension.

ADDENDUM:

Immunostains for hormone receptors are as follows:

ESTROGEN RECEPTOR: POSITIVE (70% OF CELLS, STRONG STAINING)
PROGESTERONE RECEPTOR: POSITIVE (30% OF CELLS, STRONG STAINING)

HER 2 NEU: 2+ by Herceptest, FISH pending.

ADDENDUM 2:

HER 2 NEU (by FISH): 1.4, NOT AMPLIFIED.

**** Report Electronically Signed Out ****

CLINICAL DIAGNOSIS AND HISTORY:
BIRADS IV mammogram.

PRE-OPERATIVE DIAGNOSIS:
Rule out breast cancer.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION:

RIGHT BREAST NEEDLE LOC received fresh, labeled with the patient's name, designated "RIGHT BREAST NEEDLE LOCALIZATION" is fibrofatty tissue, 6.3 x 4.4 x 1.5 cm, impaled with a needle localization wire. A radiograph accompanies the specimen. No orientation is provided. The surface is inked black. Sectioning reveals a 1.0 cm indurated mass with poorly defined margins, abutting the inked surgical margin. The fibrous tissue immediately adjacent to the mass is somewhat nodular and focally indurated as well. One section of each mass and grossly normal fibrous tissue is submitted for CBCP protocol (matching paraffin sections=A5 and A14, respectively). All remaining tissue is serially submitted for paraffin sections in 17 cassettes. The following pairings represent sections taken from the same tissue plane: A5-A6, A7-A8, A9-A10, A11-A12, A14-A15, and A16-A17.

Source: NCI Genomic Data Commons file 4c7ae22e-7457-45c5-b06d-6da8dd087812 (TCGA-A2-A0EN.8169AA00-E396-4A3E-A91C-F67B1F0B8E3E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).